Somatic mutation profile of tumor specimen TCGA-AJ-A23O-01A (aliquot TCGA-AJ-A23O-01A-11D-A159-09) from TCGA case TCGA-AJ-A23O, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 69.6 years (25,433 days).
Specimen TCGA-AJ-A23O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e50cf67a-3301-4f21-beae-1ec09e9c71be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A23O-10A (Blood Derived Normal), aliquot TCGA-AJ-A23O-10A-01D-A159-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b4041af-b5d4-4b17-8e39-1f645ec8a6ca

The open-access MAF lists 972 somatic variants for this specimen: 769 protein-altering or splice-affecting, 183 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 575, Silent 183, Frame Shift Del 109, Frame Shift Ins 29, Nonsense Mutation 27, Splice Site 13, Intron 8, In Frame Del 7, RNA 6, Splice Region 5, 3'UTR 3, Nonstop Mutation 2.

Variants (750 of 972; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ALOX12B | c.1350dup p.L451Afs*27 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | catalogued as rs746723399; ClinVar: pathogenic; called by mutect2, varscan2
- CASR | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs104893694, CM055911, CM960242, COSV56137834, COSV56139296; ClinVar: pathogenic; called by muse, varscan2
- ERBB2 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54064293; called by muse, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FGFR2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs747502397, COSV60645207, COSV60646793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPHN | c.28A>T p.N10Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as rs121908539, CM033386; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- HEXA | c.571-1G>T p.X191_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as rs185429231, CS930825, COSV51508088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.5707C>T p.R1903* | Nonsense Mutation (SNP) | VAF 17/35 reads (49%) | hotspot (GDC flag); catalogued as rs886041405, CM138435, COSV56417602; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.4990dup p.M1664Nfs*18 (on ENST00000644397 / NM_001354429.2; = p.M1606Nfs*18 on NM_001142771.2) | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as rs766484375; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1239dup p.D414Rfs*44 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs267608159; ClinVar: pathogenic; called by mutect2, varscan2
- ABCB1 | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99712441; called by muse, mutect2, varscan2
- ABCC1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.2); catalogued as COSV100578939; called by muse, mutect2, varscan2
- ABCC11 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs146149363; called by muse, mutect2, varscan2
- ABCC3 | c.4160T>A p.F1387Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV99558872; called by muse, mutect2, varscan2
- ABCF3 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1334317279, COSV53054470; called by muse, mutect2, varscan2
- ACBD3 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763152788, COSV64729745; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as rs757016425; called by mutect2, varscan2
- ACSBG2 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99397275; called by muse, mutect2, varscan2
- ACTN1 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99517471; called by muse, mutect2
- ADAM33 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs1357707682, COSV100597743; called by muse, mutect2, varscan2
- ADAMTS17 | c.5G>A p.C2Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.018); catalogued as COSV99170427; called by muse, mutect2, varscan2
- ADGRB2 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs779516984, COSV99925840; called by muse, mutect2, varscan2
- ADGRB2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180693274, COSV57080656; called by muse, mutect2, varscan2
- ADRM1 | c.793A>T p.S265C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99438700; called by muse, mutect2, varscan2
- AGRN | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101038669; called by muse, mutect2, varscan2
- AHNAK | c.10952A>G p.D3651G | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV99946282; called by muse, mutect2
- AHNAK | c.6884T>C p.L2295P | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756504944, COSV57223745; called by muse, mutect2, varscan2
- AHNAK2 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100316368; called by muse, mutect2, varscan2
- AKAP12 | c.3515A>G p.D1172G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99482774; called by muse, mutect2, varscan2
- AKAP13 | c.2107C>A p.P703T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs537413224, COSV100773319, COSV63456399; called by muse, mutect2, varscan2
- AL713999.2 | c.530T>C p.L177P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99825894; called by muse, mutect2, varscan2
- ALOX12 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52349478; called by muse, mutect2
- AMDHD1 | c.1037T>C p.M346T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99900241; called by muse, mutect2, varscan2
- AMOTL1 | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs778319796, COSV58572062; called by muse, mutect2, varscan2
- ANK2 | c.8508A>C p.Q2836H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV100000391; called by muse, mutect2, varscan2
- ANKFN1 | c.763T>A p.Y255N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV100593263; called by muse, mutect2, varscan2
- ANKRD30A | c.2809G>A p.V937M (on ENST00000611781; = p.V881M on NM_052997.2) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV100653119; called by muse, mutect2, varscan2
- ANKRD39 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs145738875, COSV100450434; called by muse, mutect2, varscan2
- ANO2 | c.1670T>C p.I557T (on ENST00000356134 / NM_001278597.3; = p.I561T on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100500141; called by muse, mutect2, varscan2
- ANO4 | c.1424A>G p.K475R (on ENST00000392977 / NM_001286615.2; = p.K440R on NM_178826.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); catalogued as COSV100152331; called by muse, mutect2
- AP001781.2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99499598; called by muse, mutect2, varscan2
- AP3D1 | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.251); catalogued as rs754096388, COSV61431618; called by muse, mutect2, varscan2
- AP3D1 | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100642473, COSV100642567; called by muse, mutect2, varscan2
- APBA1 | c.1227del p.L410Wfs*46 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV55228198; called by mutect2, pindel, varscan2
- AQP10 | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100270025; called by muse, mutect2, varscan2
- ARFGAP1 | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100796653; called by muse, mutect2, varscan2
- ARFGAP2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99040121; called by muse, mutect2, varscan2
- ARFGEF1 | c.1922-1G>T p.X641_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99141411; called by muse, mutect2, varscan2
- ARFIP2 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as COSV99601456; called by muse, mutect2, varscan2
- ARG2 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs1283820389, COSV99373687; called by muse, mutect2, varscan2
- ARHGAP21 | c.1898T>G p.V633G | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100255930; called by muse, mutect2
- ARHGAP32 | c.3392C>A p.T1131N (on ENST00000310343 / NM_001378025.1; = p.T782N on NM_014715.4) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100087233; called by muse, mutect2, varscan2
- ARHGAP4 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200174362, COSV63133813; called by muse, mutect2
- ARHGEF2 | c.1565C>T p.S522L (on ENST00000361247 / NM_001162383.2; = p.S494L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs756219943, COSV58106853; called by muse, mutect2, varscan2
- ARHGEF5 | c.83T>C p.M28T | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs752412737, COSV50218702; called by muse, mutect2, varscan2
- ARL6IP1 | c.22A>G p.S8G | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV100435814; called by muse, mutect2, varscan2
- ARNT2 | c.1895T>C p.L632P | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100308729; called by muse, mutect2, varscan2
- ASH1L | c.3763A>G p.R1255G | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100853224; called by muse, mutect2
- ASTN1 | c.3439G>A p.V1147M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.584); catalogued as rs151279922; called by muse, mutect2, varscan2
- ATG9A | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV100036824; called by muse, mutect2, varscan2
- ATP1A4 | c.2728C>T p.Q910* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100927461; called by muse, mutect2, varscan2
- ATP2B3 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99683532; called by muse, mutect2, varscan2
- ATP6V0B | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99356302; called by muse, mutect2, varscan2
- ATP8B2 | c.1075T>G p.S359A (on ENST00000672630; = p.S326A on NM_001005855.2) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as COSV100527778; called by muse, mutect2, varscan2
- ATP9A | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58763597; called by muse, mutect2, varscan2
- ATRN | c.2432A>G p.N811S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99496801; called by muse, mutect2, varscan2
- AVIL | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs752861727, COSV99142224; called by muse, mutect2, varscan2
- AXDND1 | c.2603C>T p.A868V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV100858283; called by muse, mutect2
- BBS12 | c.1456A>C p.N486H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as COSV100044860; called by muse, mutect2
- BCAN | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs775100384, COSV61255937; called by muse, mutect2
- BCL9L | c.79del p.R27Afs*18 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as COSV58321103; called by mutect2, pindel, varscan2
- BCLAF1 | c.2278_2280del p.S760del | In Frame Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs771361613; called by pindel, varscan2
- BDH1 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100827071; called by muse, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs752427670; called by mutect2, varscan2
- BECN1 | c.1068del p.L357Cfs*77 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs1395644174; called by mutect2, pindel, varscan2
- BICDL2 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs554176594, COSV99560471; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs755506199; called by mutect2, varscan2
- BIVM-ERCC5 | c.4040C>G p.S1347* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100863660, COSV63245337; called by muse, mutect2, varscan2
- BLK | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52053270, COSV99376960; called by muse, mutect2
- BLM | c.3774G>T p.E1258D | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV100757064; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPIFB4 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1020339998, COSV100971461; called by muse, mutect2, varscan2
- BRPF1 | c.3538C>A p.R1180S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100115198; called by muse, mutect2
- BTAF1 | c.5162T>A p.V1721E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795076; called by muse, mutect2, varscan2
- BTN2A1 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV100438438; called by muse, mutect2, varscan2
- C19orf57 | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100694653; called by muse, mutect2
- C1orf87 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100966973; called by muse, mutect2
- C20orf96 | c.347G>A p.R116Q (on ENST00000360321 / NM_153269.3; = p.R115Q on NM_080571.1) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100826671; called by muse, mutect2, varscan2
- C2orf78 | c.1862del p.K621Sfs*6 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV68516985; called by mutect2, varscan2
- CABIN1 | c.210+1G>T p.X70_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99572875; called by muse, mutect2, varscan2
- CACNA1A | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1469683674, COSV100801971, COSV64195535; called by muse, mutect2, varscan2
- CACNA1D | c.2021G>A p.G674D (on ENST00000350061 / NM_001128840.3; = p.G694D on NM_000720.4) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55447067, COSV99052036; called by muse, mutect2, varscan2
- CACNA1S | c.1011C>A p.F337L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100754791; called by muse, mutect2, varscan2
- CACUL1 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369808631; called by muse, mutect2, varscan2
- CAMP | c.491dup p.L164Ffs*26 (on ENST00000296435; = p.L161Ffs*26 on NM_004345.5) | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | catalogued as rs753541088; called by mutect2, pindel, varscan2
- CAMSAP2 | c.2095A>G p.S699G (on ENST00000236925 / NM_001297707.2; = p.S688G on NM_203459.3) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99373030; called by muse, mutect2
- CAPN10 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as rs2975765; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CAV1 | c.505A>T p.N169Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as COSV100591869; called by muse, mutect2, varscan2
- CBX4 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99490270; called by muse, mutect2, varscan2
- CCDC102A | c.1644G>T p.Q548H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99264946; called by muse, varscan2
- CCDC9 | c.462+1G>A p.X154_splice | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99699573; called by muse, mutect2, varscan2
- CCND2 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs1374564893, COSV99714092; called by muse, mutect2, varscan2
- CD22 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.415); catalogued as COSV99322988; called by muse, mutect2, varscan2
- CDAN1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as rs962782161, COSV99141194; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH2 | c.2308A>G p.I770V | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.996); catalogued as COSV99296163; called by muse, mutect2, varscan2
- CDH23 | c.2381A>G p.D794G | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99819602; called by muse, mutect2, varscan2
- CDHR1 | c.1937C>A p.P646H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100258571; called by muse, mutect2
- CELSR1 | c.6704A>G p.Y2235C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99417342; called by muse, mutect2, varscan2
- CENPF | c.1703A>C p.D568A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV100871587; called by muse, mutect2
- CENPP | c.519del p.F173Lfs*46 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as rs750494120; called by mutect2, pindel
- CEP250 | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs369614541; called by muse, varscan2
- CERS4 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99250504; called by muse, mutect2, varscan2
- CGN | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as rs747284823, COSV54972142; called by muse, mutect2, varscan2
- CHD1 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs892820400, COSV99399228; called by muse, mutect2, varscan2
- CHD9 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.43); catalogued as COSV101271984; called by muse, mutect2, varscan2
- CHID1 | c.890T>C p.L297P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100059528; called by muse, mutect2, varscan2
- CHRND | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773972915, COSV99285603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CLASP2 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV100222845; called by muse, mutect2
- CLEC14A | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV100643516; called by muse, mutect2, varscan2
- CLIC1 | c.186del p.Q63Sfs*37 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs1562198429; called by mutect2, pindel, varscan2
- CNNM2 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100881670; called by muse, mutect2, varscan2
- CNOT1 | c.5698C>T p.R1900C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868412977, COSV99799565; called by muse, mutect2, varscan2
- CNOT2 | c.1545T>G p.H515Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.374); catalogued as COSV99972477; called by muse, mutect2
- CNR1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs768033952, COSV100759232, COSV62986936; called by muse, mutect2, varscan2
- CNTD1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs750402772, COSV100162067; called by muse, mutect2, varscan2
- CNTN4 | c.2165C>T p.T722M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs372413516; called by muse, mutect2, varscan2
- CNTNAP4 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100270039; called by muse, mutect2
- CNTNAP5 | c.1478G>T p.C493F | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101443172; called by muse, mutect2, varscan2
- COIL | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99538037; called by muse, mutect2, varscan2
- COL11A1 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758105888, COSV100615535; called by muse, mutect2, varscan2
- COL11A2 | c.4345C>A p.P1449T (on ENST00000341947 / NM_080680.3; = p.P1342T on NM_080679.2) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.096); catalogued as COSV100553600, COSV59494409; called by muse, mutect2
- COP1 | c.1527T>G p.Y509* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100442960; called by muse, mutect2, varscan2
- COPS7A | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99976411; called by mutect2, varscan2
- COX7B | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV64864599; called by muse, mutect2, varscan2
- CR2 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100889541; called by muse, mutect2, varscan2
- CRAMP1 | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs746650368, COSV99245735; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs756999481; called by mutect2, pindel
- CSGALNACT2 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.424); catalogued as rs767837847, COSV65677066; called by muse, mutect2, varscan2
- CSMD3 | c.10828+2T>C p.X3610_splice (on ENST00000297405 / NM_001363185.1; = p.X3441_splice on NM_052900.3) | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99828414; called by muse, mutect2, varscan2
- CTIF | c.1495C>T p.L499F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99837114; called by muse, mutect2, varscan2
- CTNNA2 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.882); catalogued as COSV100559674; called by muse, mutect2, varscan2
- CTNNB1 | c.1080T>A p.A360= | Splice Region (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100846180; called by muse, mutect2, varscan2
- CUX1 | c.1961-2A>G p.X654_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99470856; called by muse, mutect2, varscan2
- CWC15 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV99688462; called by mutect2, varscan2
- CXCL1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773534431, COSV67611598; called by muse, mutect2, varscan2
- CXXC1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1395156743, COSV99495783; called by muse, mutect2, varscan2
- CYB561D1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1234971236, COSV100149777; called by muse, mutect2, varscan2
- CYFIP2 | c.2500C>T p.R834W (on ENST00000616178 / NM_001291722.2; = p.R809W on NM_014376.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs780950093, COSV100400373; called by muse, mutect2, varscan2
- CYP3A43 | c.500G>C p.S167T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV99733034; called by muse, mutect2, varscan2
- CYP4F3 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs777644178, COSV99657963; called by muse, mutect2, varscan2
- DAGLB | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as rs142949443; called by muse, mutect2, varscan2
- DARS1 | c.759T>G p.Y253* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99927408; called by muse, mutect2, varscan2
- DDHD2 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.108); catalogued as rs1456985763, COSV68157855; called by muse, mutect2, varscan2
- DENND2B | c.3014A>T p.E1005V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100567281; called by muse, mutect2, varscan2
- DENND5A | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as rs1171599889, COSV100064277; called by muse, mutect2, varscan2
- DGKQ | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99892442; called by muse, mutect2, varscan2
- DGLUCY | c.1178A>G p.Q393R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV99824134; called by muse, mutect2, varscan2
- DHH | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs768138247, COSV99908781; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIAPH2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100231668; called by muse, mutect2, varscan2
- DLAT | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.97); catalogued as rs782068514, COSV99734520; called by muse, mutect2, varscan2
- DLG3 | c.1403A>G p.E468G (on ENST00000374360 / NM_021120.4; = p.E131G on NM_020730.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99529290; called by muse, mutect2, varscan2
- DLG5 | c.5060C>A p.S1687Y | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100967327, COSV64949168; called by muse, mutect2, varscan2
- DMD | c.10920G>T p.M3640I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1233446469, COSV100626358; called by muse, mutect2, varscan2
- DNAH1 | c.5117T>C p.M1706T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101325087; called by muse, mutect2, varscan2
- DNAH11 | c.10288C>T p.Q3430* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100178075; called by muse, mutect2, varscan2
- DNAH8 | c.4418del p.N1473Ifs*15 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs778628413, COSV59486260; called by mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJB12 | c.989A>G p.Y330C (on ENST00000338820; = p.Y296C on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1393745914, COSV100123703; called by muse, mutect2, varscan2
- DNAJC1 | c.1254G>T p.E418D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV100981166, COSV65408668; called by muse, mutect2, varscan2
- DNHD1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.431); catalogued as COSV99599664; called by mutect2, varscan2
- DNMBP | c.2455-2A>G p.X819_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV60630881; called by muse, mutect2, varscan2
- DNMT3A | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs765593136, COSV53066306, COSV99260598; called by muse, mutect2, varscan2
- DOCK4 | c.5626dup p.L1876Pfs*76 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | catalogued as rs1372335757; called by mutect2, pindel, varscan2
- DPEP2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.336); catalogued as rs768027580, COSV99263083; called by muse, mutect2, varscan2
- DRG2 | c.713A>C p.Y238S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99854843; called by muse, mutect2, varscan2
- DROSHA | c.3656A>T p.D1219V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100757533; called by muse, mutect2, varscan2
- DSEL | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs1411870459, COSV100025393; called by muse, mutect2, varscan2
- DYNC2H1 | c.12195C>A p.N4065K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as COSV100517913; called by muse, mutect2, varscan2
- E2F7 | c.177del p.K59Nfs*29 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs771114476; called by mutect2, varscan2
- ECD | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100881384; called by muse, mutect2, varscan2
- EDN3 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV61107748; called by mutect2, varscan2
- EEF1AKMT1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs749657822, COSV66964693; called by muse, mutect2, varscan2
- EFNA1 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV100310250; called by muse, mutect2
- EFNA5 | c.618A>T p.Q206H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100321031, COSV60943647; called by muse, mutect2, varscan2
- EIF2AK4 | c.932A>G p.Y311C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as rs762607194, COSV99774292; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3A | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs201081411, COSV100974539; called by muse, mutect2, varscan2
- ELAC1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.035); catalogued as rs1056516547, COSV53996906; called by muse, mutect2, varscan2
- ENAM | c.2013G>T p.W671C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293686568, COSV101252977; called by muse, mutect2, varscan2
- ENOSF1 | c.774G>T p.Q258H (on ENST00000340116 / NM_001354066.2; = p.Q210H on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99200992; called by muse, mutect2
- EPG5 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.306); catalogued as COSV99956754; called by muse, mutect2, varscan2
- EPHA7 | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs149093618; called by muse, mutect2, varscan2
- EPHB3 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs535315602, COSV100382880; called by muse, mutect2, varscan2
- ERAP1 | c.1855T>G p.S619A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV99700763; called by muse, varscan2
- ERRFI1 | c.419del p.F140Sfs*35 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs34409716; called by mutect2, pindel, varscan2
- ESCO1 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV52518100; called by muse, mutect2, varscan2
- ETF1 | c.509A>T p.H170L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV100860079; called by muse, mutect2, varscan2
- ETV4 | c.1037T>A p.F346Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99292018; called by muse, mutect2, varscan2
- EVC | c.2795G>T p.R932M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99381348; called by muse, mutect2, varscan2
- F2RL1 | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688692; called by muse, mutect2
- F8 | c.4144G>A p.G1382R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100811373; called by muse, mutect2, varscan2
- FAM131C | c.779del p.P260Rfs*35 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs1399833575; called by mutect2, pindel
- FAM13B | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99221124; called by muse, mutect2, varscan2
- FAM160A2 | c.113T>C p.M38T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV99791842; called by muse, mutect2, varscan2
- FAM189A2 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57385701; called by muse, mutect2
- FAM210A | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs764696749, COSV100452284; called by muse, mutect2, varscan2
- FAM47C | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs781909617, COSV100792386; called by muse, mutect2, varscan2
- FAM47C | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs138293293, COSV100792387, COSV100792939; called by muse, mutect2, varscan2
- FAM9A | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.801); catalogued as rs1358283062, COSV101121319; called by muse, mutect2, varscan2
- FANCA | c.3115G>A p.G1039S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs773260958, COSV99981280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.795_796del p.D267Yfs*18 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1357509089; called by mutect2, pindel, varscan2
- FBXL4 | c.1343A>C p.N448T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100013939; called by muse, mutect2, varscan2
- FCGBP | c.3116G>A p.G1039D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765319387; called by mutect2, varscan2
- FCGR2A | c.197G>A p.R66H (on ENST00000271450 / NM_001136219.3; = p.R65H on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750989159, COSV54838318; called by muse, mutect2, varscan2
- FDXR | c.1094G>A p.R365H (on ENST00000293195 / NM_024417.5; = p.R371H on NM_004110.6) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs202218782; called by muse, mutect2, varscan2
- FGD5 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs199540712, COSV99547594; called by muse, mutect2, varscan2
- FLNA | c.2022G>A p.R674= | Splice Region (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100774421; called by muse, mutect2, varscan2
- FLNB | c.2441C>A p.P814H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99912258; called by muse, mutect2, varscan2
- FMO4 | c.1322T>C p.I441T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV100882038; called by muse, mutect2, varscan2
- FMO5 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV99566820; called by muse, mutect2, varscan2
- FNDC1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544765580, COSV51936499; called by muse, mutect2, varscan2
- FNDC5 | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV100992465; called by muse, mutect2, varscan2
- FOXC2 | c.595del p.H199Tfs*2 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV57444358; called by mutect2, varscan2
- FOXK2 | c.876T>G p.Y292* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100081899; called by muse, mutect2, varscan2
- FRMD4B | c.2593G>T p.V865L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101273378; called by muse, mutect2, varscan2
- FSCB | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1313066557, COSV100469022, COSV100470054; called by muse, mutect2, varscan2
- FTL | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV99508996; called by muse, mutect2, varscan2
- FUBP1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as COSV53927193; called by muse, mutect2
- FURIN | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99184636; called by muse, mutect2, varscan2
- FUT2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.179); catalogued as rs760999180, COSV67179338; called by muse, mutect2, varscan2
- GALNT18 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756741253, COSV99924106; called by muse, mutect2, varscan2
- GALR2 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV100135006; called by muse, mutect2, varscan2
- GATB | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99858850; called by muse, mutect2, varscan2
- GBP3 | c.1507del p.M503Wfs*7 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as COSV99352672; called by mutect2, pindel, varscan2
- GEMIN4 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.947); catalogued as rs531320666, COSV56745081; called by muse, mutect2, varscan2
- GET3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV100628148; called by muse, mutect2
- GFPT1 | c.2098T>C p.*700Rext*26 (on ENST00000357308 / NM_001244710.2; = p.*682Rext*26 on NM_002056.4) | Nonstop Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100622713; called by muse, mutect2, varscan2
- GLRA4 | c.203-1G>T p.X68_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV101009596; called by muse, mutect2, varscan2
- GLRX2 | c.413A>G p.H138R (on ENST00000367439 / NM_197962.3; = p.H139R on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100814163; called by muse, mutect2, varscan2
- GMPR | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as rs757224478, COSV52475263; called by muse, mutect2
- GNAZ | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as COSV99320537; called by muse, mutect2, varscan2
- GOLM1 | c.1162A>T p.I388L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV101165197; called by muse, mutect2, varscan2
- GPATCH8 | c.3110A>G p.H1037R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754711234, COSV100132526; called by muse, mutect2, varscan2
- GPR101 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99981305; called by muse, mutect2, varscan2
- GPR146 | c.521G>C p.R174P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV52465431, COSV52466314; called by muse, mutect2, varscan2
- GPRIN2 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782597276, COSV100966323; called by muse, mutect2
- GRM3 | c.2167C>T p.R723W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560446375, COSV64469346; called by muse, mutect2, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GTF3C5 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs200358389, COSV100565297; called by muse, varscan2
- GUCY1A1 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs780037516, COSV99637385; called by muse, mutect2, varscan2
- HCK | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52945814, COSV99393871; called by muse, mutect2, varscan2
- HEATR1 | c.5722T>C p.S1908P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857534; called by muse, mutect2
- HEATR5B | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1468465476, COSV99248683; called by muse, mutect2, varscan2
- HIC1 | c.1433G>T p.G478V (on ENST00000322941 / NM_001098202.1; = p.G459V on NM_006497.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.48); catalogued as COSV99557901; called by muse, mutect2, varscan2
- HIGD2A | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV99220853; called by muse, mutect2, varscan2
- HIPK3 | c.1018G>T p.V340F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100305544; called by muse, varscan2
- HNRNPAB | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.583); catalogued as rs778893474, COSV100359285; called by mutect2, varscan2
- HNRNPD | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100002793; called by muse, mutect2
- HNRNPDL | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99787028; called by muse, mutect2, varscan2
- HNRNPL | c.972C>G p.Y324* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99670119; called by muse, varscan2
- HORMAD1 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.341); catalogued as COSV100463922; called by muse, varscan2
- HPSE2 | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs753802345, COSV100985359; called by muse, mutect2, varscan2
- HSP90AB1 | c.1558T>G p.Y520D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100806999, COSV62336695; called by muse, mutect2, varscan2
- HSPG2 | c.12085G>T p.V4029L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100760727; called by muse, mutect2, varscan2
- HTR7 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519210; called by muse, mutect2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs757667533; called by mutect2, varscan2
- IFNAR1 | c.1400T>C p.V467A | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV99531515; called by muse, varscan2
- IGDCC4 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100732761; called by muse, mutect2, varscan2
- IGKV2D-24 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs541448935; called by muse, mutect2, varscan2
- IGLON5 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs766874103, COSV54534879; called by muse, mutect2, varscan2
- IKBKE | c.1709A>C p.E570A | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100897943; called by muse, mutect2, varscan2
- IL17RA | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV100082947; called by muse, mutect2, varscan2
- ING3 | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59950552; called by muse, mutect2, varscan2
- INPP5D | c.2288G>A p.S763N (on ENST00000445964 / NM_001017915.3; = p.S762N on NM_005541.5) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100856594; called by muse, mutect2
- INPPL1 | c.3741G>T p.K1247N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99995977; called by muse, mutect2, varscan2
- IQCN | c.1143G>A p.M381I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1452763083, COSV101148450; called by muse, mutect2, varscan2
- IQSEC1 | c.2875T>C p.S959P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV99831508; called by mutect2, varscan2
- IRF9 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1223992422, COSV100138087; called by muse, mutect2, varscan2
- ITGAE | c.1795G>C p.A599P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99560605, COSV99561817; called by muse, mutect2, varscan2
- JADE1 | c.410G>A p.S137N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.348); catalogued as COSV56907489; called by muse, mutect2
- JOSD2 | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.337); catalogued as COSV101209081; called by muse, mutect2, varscan2
- KAT2A | c.1085T>C p.M362T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99863442; called by mutect2, varscan2
- KAT6B | c.2188A>G p.I730V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as COSV99767587; called by muse, mutect2, varscan2
- KCNJ3 | c.557A>G p.Q186R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.535); catalogued as COSV99715434; called by muse, mutect2, varscan2
- KCNMA1 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV99695814; called by muse, mutect2, varscan2
- KCNN4 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99486973; called by muse, mutect2, varscan2
- KDELR1 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100416405; called by muse, mutect2
- KDM6B | c.3720A>C p.E1240D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV99640932; called by muse, mutect2, varscan2
- KIAA2026 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs752265027, COSV67353972; called by muse, mutect2, varscan2
- KIF24 | c.1982dup p.P662Afs*10 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs570788521; called by mutect2, varscan2
- KIF26B | c.2716G>A p.A906T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs773883282, COSV63641009; called by muse, varscan2
- KLHL23 | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); catalogued as COSV99775615; called by muse, mutect2, varscan2
- KLHL40 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55135120; called by muse, mutect2
- KLHL41 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99500286; called by muse, mutect2, varscan2
- KNTC1 | c.4282A>G p.T1428A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV100338077; called by muse, mutect2, varscan2
- KNTC1 | c.6247C>T p.P2083S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756158800, COSV100338078; called by muse, mutect2
- KPNB1 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99267931; called by muse, mutect2, varscan2
- KRT6B | c.1501A>G p.S501G | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99360544; called by muse, mutect2
- L3MBTL3 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766315177, COSV100695823, COSV100696473; called by muse, mutect2, varscan2
- LAMB4 | c.2332G>T p.G778* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52722597, COSV52723548; called by muse, mutect2, varscan2
- LAMC2 | c.1766G>A p.G589D | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917214; called by muse, mutect2, varscan2
- LARP4B | c.1325C>A p.A442E | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.448); catalogued as COSV100295171; called by muse, mutect2, varscan2
- LARS1 | c.2930G>T p.G977V (on ENST00000394434 / NM_020117.11; = p.G950V on NM_016460.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99198516; called by muse, mutect2, varscan2
- LCOR | c.786T>A p.D262E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV100603548; called by muse, mutect2, varscan2
- LIG1 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531348489, COSV99618652; called by muse, mutect2, varscan2
- LIN9 | c.1550C>A p.A517E (on ENST00000366808 / NM_001270410.2; = p.A462E on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100067174; called by muse, mutect2, varscan2
- LINGO4 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV100764945; called by muse, mutect2, varscan2
- LMAN1L | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400291704, COSV100547617; called by muse, mutect2, varscan2
- LMBR1L | c.574T>G p.Y192D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV99918619; called by muse, mutect2, varscan2
- LMNB1 | c.551T>C p.L184S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99745705; called by muse, mutect2, varscan2
- LMO7 | c.3440G>T p.S1147I (on ENST00000357063; = p.S828I on NM_005358.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as COSV100412693; called by muse, mutect2, varscan2
- LRRIQ1 | c.4401C>G p.N1467K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV101279770; called by muse, mutect2, varscan2
- LSMEM2 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371304100; called by muse, mutect2, varscan2
- LYSMD4 | c.863T>G p.F288C (on ENST00000409796 / NM_001284417.2; = p.F289C on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV100230565; called by muse, mutect2, varscan2
- MAEA | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV99295270; called by muse, mutect2, varscan2
- MAGEE1 | c.1852C>T p.L618F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100819332; called by muse, varscan2
- MAP3K5 | c.2357A>G p.Q786R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100752607; called by muse, mutect2, varscan2
- MCTP1 | c.2651T>A p.I884N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100386568; called by muse, mutect2, varscan2
- MED13L | c.571T>G p.L191V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.893); catalogued as COSV99928183; called by muse, mutect2, varscan2
- MED14 | c.242+1G>C p.X81_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100247389; called by muse, varscan2
- MEGF6 | c.2969G>A p.C990Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99619754; called by muse, mutect2, varscan2
- MFSD10 | c.1137C>A p.C379* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99296160; called by muse, mutect2, varscan2
- MGA | c.1995T>G p.F665L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99579046; called by muse, mutect2, varscan2
- MGST2 | c.309del p.K103Nfs*8 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as COSV55498546; called by mutect2, pindel, varscan2
- MKI67 | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100896324; called by mutect2, varscan2
- MOXD1 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60946230; called by muse, mutect2
- MPP2 | c.376-3del | Splice Region (DEL) | VAF 10/26 reads (38%) | catalogued as rs769731446; called by mutect2, pindel, varscan2
- MRPL21 | c.378G>C p.E126D | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100751884; called by muse, mutect2, varscan2
- MTCL1 | c.3950C>T p.A1317V (on ENST00000306329 / NM_001378206.1; = p.A998V on NM_015210.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100093851; called by muse, mutect2, varscan2
- MTCL1 | c.5435C>T p.S1812L (on ENST00000306329 / NM_001378206.1; = p.S1493L on NM_015210.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs745335148, COSV100093859; called by muse, mutect2, varscan2
- MTG2 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63693574; called by muse, mutect2, varscan2
- MTSS1 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100274575; called by muse, mutect2
- MTTP | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99644884; called by muse, mutect2, varscan2
- MUC16 | c.14180A>G p.D4727G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.003); catalogued as COSV101198814; called by muse, mutect2
- MUC6 | c.3044C>T p.T1015M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs367909154; called by muse, mutect2, varscan2
- MUSK | c.2041A>G p.S681G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs374669213; called by muse, mutect2, varscan2
- MYB | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214660; called by muse, mutect2, varscan2
- MYBPC2 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.991); catalogued as COSV100731679; called by muse, mutect2, varscan2
- MYCBP2 | c.3025T>A p.Y1009N (on ENST00000357337; = p.Y1047N on NM_015057.5) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as COSV100629546; called by muse, mutect2, varscan2
- MYH7 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs4981473, COSV100805836; ClinVar: uncertain significance; called by muse, mutect2
- MYH7B | c.4858G>T p.V1620L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.105); catalogued as COSV99328030; called by muse, mutect2, varscan2
- MYO18A | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV62867344; called by muse, mutect2
- MYT1L | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.9); PolyPhen benign (0.039); catalogued as rs1319225926, COSV101219468; called by muse, mutect2, varscan2
- NADSYN1 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100034513; called by muse, mutect2, varscan2
- NBR1 | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100357746; called by muse, mutect2, varscan2
- NCKAP5 | c.4141A>G p.I1381V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100490700; called by muse, mutect2, varscan2
- NCOA1 | c.3210C>A p.H1070Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as COSV99945543; called by muse, mutect2, varscan2
- NCOR2 | c.1775G>A p.S592N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100657024; called by muse, mutect2, varscan2
- NDST4 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs144091320; called by muse, mutect2, varscan2
- NDUFAF7 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as COSV99135464; called by muse, mutect2, varscan2
- NDUFS2 | c.179A>C p.H60P | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100917383; called by muse, mutect2, varscan2
- NEB | c.10700A>G p.K3567R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs562419268, COSV99417448; called by muse, mutect2, varscan2
- NES | c.2369C>A p.S790Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100957795; called by muse, mutect2, varscan2
- NF1 | c.233dup p.N78Kfs*29 | Frame Shift Ins (INS) | VAF 11/21 reads (52%) | catalogued as COSV62211453; called by mutect2, varscan2
- NHLH1 | c.321dup p.D108Rfs*8 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | catalogued as rs760805876; called by mutect2, pindel, varscan2
- NISCH | c.3785G>A p.S1262N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100401395; called by muse, mutect2
- NIT1 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100919052; called by muse, mutect2, varscan2
- NKD2 | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99723897; called by muse, mutect2, varscan2
- NLGN1 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100848936; called by muse, mutect2, varscan2
- NR1H3 | c.1205T>C p.L402P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100211191; called by muse, mutect2, varscan2
- NR2E1 | c.373C>A p.L125I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100934402; called by muse, mutect2, varscan2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | catalogued as rs774629025; called by mutect2, varscan2
- NRXN3 | c.1465G>T p.G489* (on ENST00000335750 / NM_001330195.2; = p.G116* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100201957; called by muse, mutect2, varscan2
- NSD1 | c.3394G>A p.G1132R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs570278983, COSV100728597, COSV61786245; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NT5DC2 | c.858T>A p.D286E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV58739762; called by muse, mutect2, varscan2
- NTF3 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100451079; called by muse, mutect2, varscan2
- NTRK3 | c.1568G>A p.C523Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.402); catalogued as COSV58142168; called by muse, mutect2
- NUB1 | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100879247; called by muse, mutect2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs1566064574; called by mutect2, pindel, varscan2
- NUFIP2 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99837284; called by muse, mutect2, varscan2
- NUP210L | c.5417G>A p.R1806Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs866123890, COSV99667512, COSV99668397; called by muse, mutect2
- NUP98 | c.3886T>C p.Y1296H (on ENST00000359171 / NM_001365126.1; = p.Y1279H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.997); catalogued as rs527476688, COSV100261792; called by muse, mutect2, varscan2
- NYNRIN | c.4583A>T p.D1528V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV101230532; called by muse, mutect2
- OBSL1 | c.2913A>T p.E971D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.073); catalogued as COSV99216449; called by muse, mutect2, varscan2
- OBSL1 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs371714401; called by muse, mutect2, varscan2
- OCA2 | c.674C>A p.S225Y | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100667117; called by muse, mutect2, varscan2
- ODF2 | c.1400+2T>C p.X467_splice (on ENST00000434106 / NM_153433.2; = p.X443_splice on NM_002540.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100654482; called by muse, mutect2, varscan2
- ODF2L | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99643922; called by muse, mutect2
- OGA | c.1705T>A p.Y569N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100761689; called by muse, mutect2, varscan2
- OGA | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.093); catalogued as COSV100761690; called by muse, mutect2, varscan2
- OR10G8 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101461809; called by muse, mutect2, varscan2
- OR10J3 | c.409A>G p.M137V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as COSV100171650; called by muse, mutect2, varscan2
- OR10X1 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100936614, COSV63767666; called by muse, mutect2, varscan2
- OR13A1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100980987; called by muse, varscan2
- OR51M1 | c.968A>G p.K323R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.011); catalogued as COSV100150173, COSV100150441; called by muse, mutect2
- OR51V1 | c.440T>A p.I147N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100343285; called by muse, mutect2, varscan2
- OR5H6 | c.284C>T p.P95L (on ENST00000642105; = p.P79L on NM_001005479.2) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs370396789; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs746200712; called by mutect2, varscan2
- OR6K6 | c.374G>A p.C125Y (on ENST00000368144; = p.C101Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100933702; called by muse, mutect2
- OR8H3 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100538817; called by muse, mutect2, varscan2
- OTUD7B | c.2282G>T p.R761M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.346); catalogued as COSV100967428, COSV100967453; called by muse, mutect2
- PAF1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99655661; called by muse, mutect2, varscan2
- PAG1 | c.1210A>G p.T404A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV99597168; called by muse, mutect2, varscan2
- PAPOLB | c.768A>C p.R256S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271308; called by muse, mutect2, varscan2
- PARN | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100420762, COSV58369046; called by muse, mutect2, varscan2
- PARP8 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.432); catalogued as COSV99890442; called by muse, mutect2, varscan2
- PCDH9 | c.2596A>T p.N866Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV100119234; called by muse, mutect2
- PCDHB10 | c.551G>A p.G184D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.001); catalogued as COSV99503924, COSV99505040; called by muse, mutect2
- PCDHB16 | c.1261C>A p.L421I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53360376; called by muse, mutect2, varscan2
- PCDHGA8 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.479); catalogued as COSV99533625; called by muse, mutect2, varscan2
- PCLO | c.14689C>T p.R4897C | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429073; called by muse, mutect2, varscan2
- PCNX3 | c.4529G>A p.G1510D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV100856138; called by muse, mutect2, varscan2
- PCOLCE2 | c.890G>A p.C297Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99930464; called by muse, mutect2, varscan2
- PDCD11 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV100874272; called by muse, mutect2, varscan2
- PDE1B | c.1565del p.P522Hfs*25 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs780236743; called by mutect2, varscan2
- PDE5A | c.1868A>C p.Q623P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308479; called by muse, mutect2, varscan2
- PDPR | c.1128G>T p.Q376H | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.489); catalogued as COSV99847940; called by muse, mutect2, varscan2
- PDS5B | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.947); catalogued as COSV59726821; called by muse, mutect2, varscan2
- PDZD2 | c.3008G>T p.R1003L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV56865963, COSV99224254; called by muse, mutect2, varscan2
- PEX6 | c.1884A>C p.A628= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as rs779124738, COSV99769605; called by muse, mutect2, varscan2
- PFKFB2 | c.1357T>G p.F453V | Missense Mutation (SNP) | VAF 40/270 reads (15%) | PolyPhen benign (0); catalogued as COSV100891914, COSV65550495; called by muse, mutect2, varscan2
- PFKM | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.291); catalogued as COSV100402326; called by muse, mutect2
- PGR | c.2295G>T p.W765C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54810046, COSV99677666; called by muse, mutect2, varscan2
- PHACTR4 | c.214C>T p.R72* (on ENST00000373839 / NM_001350159.2; = p.R82* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as rs1468459755, COSV65783253; called by muse, mutect2, varscan2
- PHC1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs143469762; called by muse, mutect2, varscan2
- PHETA1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100825320; called by muse, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs769717544; called by mutect2, varscan2
- PHLPP1 | c.1966C>G p.L656V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV99407693, COSV99408201; called by muse, mutect2, varscan2
- PHLPP1 | c.3767C>T p.T1256I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99407697; called by muse, mutect2, varscan2
- PIGA | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100363399; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs755454854; called by pindel, varscan2
- PISD | c.967G>A p.A323T (on ENST00000439502 / NM_001326412.1; = p.A289T on NM_014338.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99837205; called by muse, mutect2, varscan2
- PKD1 | c.6623G>A p.G2208D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as rs1428083805, COSV99237485; called by muse, mutect2, varscan2
- PKD1L1 | c.4222C>T p.P1408S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56969401, COSV99218944; called by muse, mutect2
- PKD2 | c.2053T>C p.S685P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52939454, COSV99417046; called by muse, mutect2, varscan2
- PKD2L1 | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100559337; called by muse, mutect2, varscan2
- PKHD1 | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs979052480, COSV100581867; called by muse, mutect2
- PKP1 | c.881A>G p.D294G | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV99825027; called by muse, mutect2, varscan2
- PLA2G15 | c.695dup p.V233Rfs*47 | Frame Shift Ins (INS) | VAF 8/31 reads (26%) | catalogued as rs763871300; called by mutect2, varscan2
- PLA2G2A | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs1047441725, COSV100908612; called by muse, mutect2, varscan2
- PLAAT1 | c.616C>T p.R206W (on ENST00000650797; = p.R101W on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs766699838, COSV53233045, COSV99290591; called by muse, mutect2, varscan2
- PLAUR | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV99655053; called by muse, mutect2, varscan2
- PLEKHG3 | c.1784T>C p.L595P (on ENST00000394691; = p.L651P on NM_001308147.2) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1252323608, COSV99906390; called by muse, mutect2, varscan2
- PLEKHM2 | c.2971T>A p.F991I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53818530, COSV99606499; called by muse, mutect2, varscan2
- PLGRKT | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99803609; called by muse, mutect2, varscan2
- PLXNB2 | c.274A>G p.M92V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100833922; called by muse, mutect2, varscan2
- PLXND1 | c.3131C>T p.P1044L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs867989433, COSV60711637; called by muse, mutect2, varscan2
- POGK | c.1375G>T p.G459* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV63311369, COSV63311976; called by muse, mutect2
- POLR1A | c.2641A>G p.M881V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99807280; called by muse, mutect2, varscan2
- PPP1R1A | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs1220829848, COSV99226304; called by muse, mutect2
- PPP1R32 | c.372del p.T125Pfs*51 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV58544559; called by mutect2, pindel, varscan2
- PPP4R1 | c.918G>T p.W306C (on ENST00000400556 / NM_001042388.3; = p.W289C on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53283996, COSV99553274; called by muse, mutect2, varscan2
- PRDM12 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99446137; called by muse, varscan2
- PREP | c.917T>C p.L306P (on ENST00000369110; = p.L372P on NM_002726.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100963785; called by muse, mutect2, varscan2
- PRF1 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs201382038, CM1111576, COSV100942555, COSV99059361; called by muse, mutect2, varscan2
- PRKACA | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1192231636, COSV58069112; called by mutect2, varscan2
- PROSER1 | c.86T>A p.V29E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771944722, COSV100612701; called by muse, varscan2
- PRPF4 | c.139T>G p.S47A (on ENST00000374198 / NM_001322267.2; = p.S48A on NM_004697.5) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1348555932, COSV100950641; called by muse, mutect2, varscan2
- PRPSAP1 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100221656; called by muse, mutect2, varscan2
- PRR15L | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV99846475; called by muse, mutect2, varscan2
- PRRT2 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV99569399; called by muse, mutect2, varscan2
- PRRT2 | c.640G>C p.A214P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745594874, CM163209, COSV54881935, COSV54882487; ClinVar: uncertain significance / benign / likely benign; called by muse, varscan2
- PRUNE2 | c.6235A>G p.S2079G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV65040649; called by muse, mutect2, varscan2
- PSAT1 | c.954A>C p.K318N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV100716528; called by muse, mutect2, varscan2
- PSMC5 | c.634A>T p.I212F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99856288; called by muse, mutect2, varscan2
- PSMD7 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54698035, COSV99542645; called by muse, mutect2
- PTEN | c.461del p.F154Sfs*5 | Frame Shift Del (DEL) | VAF 87/155 reads (56%) | catalogued as CD110180, COSV64304545, COSV64306462; called by mutect2, pindel, varscan2
- PTGIS | c.311T>C p.M104T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99720759; called by muse, mutect2, varscan2
- PTGR1 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99437098; called by muse, mutect2, varscan2
- PTGS1 | c.1406T>G p.F469C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99792992; called by muse, mutect2, varscan2
- PTPRF | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV100740730; called by muse, mutect2, varscan2
- PTPRF | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1317417745, COSV100740731; called by muse, mutect2, varscan2
- PTPRN | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776445081, COSV55345292; called by muse, mutect2, varscan2
- PUDP | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.065); catalogued as rs961213796, COSV101127839; called by muse, mutect2
- RAB11FIP5 | c.1956dup p.K653Qfs*112 | Frame Shift Ins (INS) | VAF 8/19 reads (42%) | catalogued as rs755409958; called by mutect2, varscan2
- RAD51D | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV100239046; called by muse, mutect2, varscan2
- RAN | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99619671; called by muse, mutect2, varscan2
- RAPH1 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV55588784; called by muse, mutect2, varscan2
- RASAL2 | c.2863C>A p.P955T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs755657025, COSV100862498; called by muse, mutect2, varscan2
- RASSF8 | c.159A>C p.L53F | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99280739; called by muse, mutect2, varscan2
- RBM5 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100762196; called by muse, mutect2
- RBM5 | c.441T>A p.F147L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100762197; called by muse, mutect2
- RC3H2 | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100106391; called by muse, mutect2
- RELL2 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs374920239; called by muse, mutect2
- RFTN2 | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs138508855, COSV54389151, COSV99695348; called by muse, mutect2, varscan2
- RHCE | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs201407774, CM058209, COSV53801296; called by muse, mutect2, varscan2
- RHOA | c.67A>T p.I23L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV101371100; called by muse, mutect2, varscan2
- RIMS2 | c.2141C>A p.P714H (on ENST00000666250 / NM_001348490.2; = p.P522H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99164050; called by muse, mutect2, varscan2
- RNF17 | c.2294A>G p.N765S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as COSV99692552; called by muse, mutect2, varscan2
- RNF20 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs765010969, COSV100874307; called by muse, mutect2, varscan2
- RNF40 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV100221953; called by muse, mutect2, varscan2
- RNF40 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1464801491, COSV61216690; called by muse, mutect2, varscan2
- RORC | c.518C>A p.P173H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV100561849, COSV59093866; called by muse, mutect2, varscan2
- RPA4 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV61258617; called by muse, mutect2
- RRAGB | c.473G>A p.R158H (on ENST00000262850 / NM_016656.4; = p.R130H on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1474210216, COSV99469191; called by muse, mutect2, varscan2
- RTF1 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV67477730; called by muse, mutect2, varscan2
- RUBCN | c.830dup p.V278Sfs*16 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | catalogued as rs745498865; called by mutect2, varscan2
- RXFP1 | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.405); catalogued as COSV100313616; called by muse, mutect2, varscan2
- RYR2 | c.13120G>T p.D4374Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63683106; called by muse, mutect2
- S100A7L2 | c.101A>C p.N34T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100906851; called by muse, mutect2, varscan2
- SALL2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100444227; called by muse, mutect2, varscan2
- SAMD1 | c.852T>A p.D284E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV99513745; called by muse, mutect2, varscan2
- SBF2 | c.4448A>G p.H1483R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV99813591; called by muse, mutect2, varscan2
- SCAF4 | c.3118C>T p.R1040W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs202128594, COSV99532064; called by mutect2, varscan2
- SCAMP1 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100210370; called by muse, mutect2, varscan2
- SCARB2 | c.517G>C p.V173L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99357842; called by muse, mutect2, varscan2
- SCYL1 | c.845T>A p.I282N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99533905; called by muse, mutect2, varscan2
- SDK1 | c.5353G>A p.G1785R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375894303; called by muse, mutect2, varscan2
- SEC13 | c.431_433del p.K144del (on ENST00000350697 / NM_183352.3; = p.K147del on NM_030673.4) | In Frame Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs1450002854; called by pindel, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SELENBP1 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100923618; called by muse, mutect2, varscan2
- SEMA4A | c.625A>C p.M209L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100740488; called by muse, mutect2, varscan2
- SEMA5B | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52089825, COSV99531138; called by muse, mutect2, varscan2
- SERGEF | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs150637785; called by muse, mutect2, varscan2
- SETD2 | c.3850C>A p.H1284N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1387669118, COSV100338407; ClinVar: benign; called by muse, mutect2, varscan2
- SEZ6L | c.1682-2A>G p.X561_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV50667207; called by muse, mutect2, varscan2
- SF3B2 | c.1973C>A p.P658H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100488329; called by muse, mutect2, varscan2
- SF3B3 | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV100209686; called by muse, mutect2, varscan2
- SGSM1 | c.3208G>A p.V1070I (on ENST00000400359 / NM_001039948.4; = p.V1009I on NM_133454.3) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs201954600; called by muse, mutect2, varscan2
- SHCBP1 | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100317175; called by muse, mutect2, varscan2
- SHROOM2 | c.2612G>A p.G871D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101098317; called by muse, mutect2, varscan2
- SLC10A3 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); catalogued as COSV99682045; called by muse, mutect2, varscan2
- SLC23A1 | c.1618A>G p.S540G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99497187; called by muse, mutect2, varscan2
- SLC25A31 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99829301; called by muse, varscan2
- SLC25A31 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs752061699, COSV55420111; called by muse, varscan2
- SLC35D3 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100090442; called by muse, mutect2
- SLC39A5 | c.641T>C p.L214P | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV99907390; called by muse, mutect2, varscan2
- SLC4A11 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs1362719565, COSV66261027; called by muse, mutect2, varscan2
- SLC6A15 | c.991C>A p.H331N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV99880368; called by muse, mutect2, varscan2
- SLC6A2 | c.1372C>A p.L458M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV54915356; called by muse, mutect2, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs749004401; called by mutect2, varscan2
- SLCO2B1 | c.1820G>T p.R607M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99214419; called by muse, mutect2, varscan2
- SLX4 | c.2098G>A p.G700R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367749586, CM116406, COSV53562633; called by muse, mutect2, varscan2
- SMAP1 | c.538G>A p.E180K (on ENST00000370455 / NM_001044305.3; = p.E153K on NM_021940.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.476); catalogued as rs1214328224, COSV57643799; called by muse, mutect2, varscan2
- SMARCAD1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100758811; called by muse, mutect2, varscan2
- SMARCAL1 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as CM071093, COSV61920449; called by muse, mutect2, varscan2
- SMC1A | c.3419T>C p.L1140P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447167; called by muse, mutect2, varscan2
- SMC5 | c.374T>A p.I125N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100747000; called by muse, mutect2, varscan2
- SNCG | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100813806; called by muse, mutect2, varscan2
- SPAG5 | c.2815G>T p.V939L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV99881790; called by muse, mutect2, varscan2
- SPARC | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99163737; called by muse, mutect2, varscan2
- SPATA17 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65124329; called by muse, mutect2
- SPATA31D1 | c.1169del p.L390* | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | catalogued as COSV61199324; called by mutect2, pindel, varscan2
- SPRED3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100634172; called by muse, mutect2, varscan2
- SPTBN1 | c.2917del p.E973Kfs*26 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as COSV61689141; called by pindel, varscan2
- SPTBN1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100442053; called by muse, varscan2
- SRGAP3 | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100840791; called by muse, mutect2, varscan2
- ST3GAL4 | c.779C>G p.T260S (on ENST00000392669 / NM_001254758.1; = p.T256S on NM_006278.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99917331; called by muse, mutect2, varscan2
- STAC | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99829676; called by muse, mutect2, varscan2
- STAMBP | c.1082A>T p.E361V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277634; called by muse, mutect2, varscan2
- STARD8 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99366430; called by muse, mutect2
- STEAP4 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100112457; called by muse, mutect2, varscan2
- STK11IP | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs752821805, COSV99822465; called by muse, mutect2, varscan2
- STK31 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757104552, COSV63453939, COSV63459549; called by muse, mutect2
- STK32B | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750813196, COSV51500112; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV100561609; called by muse, varscan2
- STX3 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100275671; called by muse, mutect2, varscan2
- SUPV3L1 | c.878T>A p.I293N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100669555; called by muse, mutect2
- SUSD4 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV100663583; called by muse, mutect2, varscan2
- SYTL3 | c.937G>A p.A313T (on ENST00000611299 / NM_001242394.1; = p.A245T on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs770769979, COSV99791679; called by muse, mutect2, varscan2
- TAB1 | c.775A>G p.S259G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV99335931; called by muse, mutect2, varscan2
- TAB3 | c.1081G>T p.G361C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99915966, COSV99916790; called by muse, mutect2, varscan2
- TACC1 | c.2369T>A p.L790Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99393152; called by muse, mutect2, varscan2
- TAF1L | c.3856T>C p.C1286R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644302; called by muse, mutect2, varscan2
- TAF4 | c.3020C>T p.T1007I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99433704; called by muse, mutect2, varscan2
- TAOK1 | c.175A>G p.M59V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99913699; called by muse, mutect2
- TAPBP | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV99801697; called by muse, mutect2, varscan2
- TARS2 | c.1816A>G p.K606E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV60875538; called by muse, mutect2
- TASOR | c.2250T>A p.D750E (on ENST00000355628 / NM_001365636.2; = p.D354E on NM_015224.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100843420; called by muse, mutect2
- TBC1D1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs752931895, COSV54713521; called by muse, mutect2, varscan2
- TBC1D2B | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100316974; called by muse, mutect2, varscan2
- TBC1D8 | c.3301T>C p.F1101L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99961408; called by muse, mutect2, varscan2
- TBK1 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100538071; called by muse, mutect2, varscan2
- TBX2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as COSV99538703; called by muse, mutect2, varscan2
- TCEAL3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV99685235; called by muse, mutect2, varscan2
- TCF3 | c.1717G>T p.G573W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99513750; called by muse, mutect2, varscan2
- TEAD1 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV57567763; called by muse, mutect2, varscan2
- TEKT3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV100106896; called by muse, mutect2, varscan2
- TENM1 | c.7271C>T p.T2424I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as COSV100949413; called by muse, mutect2, varscan2
- TENM2 | c.1178A>G p.Y393C (on ENST00000518659 / NM_001122679.2; = p.Y202C on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1484292245, COSV101318245; called by muse, mutect2, varscan2
- TET3 | c.5243dup p.T1749Hfs*5 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs759623160; called by mutect2, varscan2
- TEX15 | c.7015-1G>T p.X2339_splice (on ENST00000256246; = p.X2722_splice on NM_001350162.2) | Splice Site (SNP) | VAF 16/91 reads (18%) | catalogued as rs1480242388, COSV56349647, COSV99820965; called by muse, mutect2, varscan2
- TEX15 | c.4969T>G p.C1657G (on ENST00000256246; = p.C2040G on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV99820966; called by muse, mutect2, varscan2
- TFB2M | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs746323608, COSV63625169; called by muse, mutect2, varscan2
- TFIP11 | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as COSV101316439; called by muse, mutect2, varscan2
- TGM1 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as rs764380548, CM092053, COSV52866278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THAP12 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.129); catalogued as COSV99472820; called by muse, mutect2, varscan2
- THSD7A | c.3350A>G p.N1117S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.771); catalogued as COSV101448580; called by muse, mutect2, varscan2
- TIMP3 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs757258891, COSV56665522; called by muse, mutect2, varscan2
- TJP1 | c.1118A>G p.E373G | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1420147753, COSV100632478; called by muse, mutect2, varscan2
- TMEM167A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as rs759505218, COSV99982270; called by mutect2, varscan2
- TMEM72 | c.333G>A p.W111* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV101273500; called by muse, mutect2, varscan2
- TMIGD2 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56667562, COSV56668501; called by muse, mutect2
- TNFAIP3 | c.1411A>G p.S471G | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1031393159, COSV99396465; called by muse, mutect2, varscan2
- TNK1 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100294774; called by muse, mutect2, varscan2
- TNRC6B | c.5228C>T p.A1743V (on ENST00000454349 / NM_001162501.2; = p.A1633V on NM_015088.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV100109275; called by mutect2, varscan2
- TNS2 | c.1420A>G p.T474A (on ENST00000314250 / NM_170754.4; = p.T484A on NM_015319.2) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100047659; called by muse, mutect2, varscan2
- TOGARAM1 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs1488629211, COSV100753020; called by muse, mutect2, varscan2
- TPH2 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs2887147, COSV61591116; called by muse, mutect2, varscan2
- TRA2A | c.160T>G p.S54A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV99767549; called by muse, mutect2, varscan2
- TRA2B | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99373218; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as rs1470581004, COSV50551177; called by muse, mutect2
- TRAFD1 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99986824; called by muse, mutect2, varscan2
- TRANK1 | c.8392C>A p.H2798N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100081993; called by muse, mutect2, varscan2
- TRAPPC11 | c.3364G>A p.G1122S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV100591741; called by muse, mutect2, varscan2
- TRBV3-1 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1355032179; called by muse, mutect2, varscan2
- TRIM24 | c.2762G>A p.S921N (on ENST00000343526 / NM_015905.3; = p.S887N on NM_003852.4) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100630751; called by muse, mutect2, varscan2
- TRIM37 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV99232492; called by muse, mutect2, varscan2
- TRIM67 | c.1446A>C p.K482N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100792067; called by muse, mutect2, varscan2
- TRIM67 | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100792068; called by muse, mutect2, varscan2
- TRIP12 | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.11); catalogued as COSV99389653; called by muse, mutect2, varscan2
- TRMT10B | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV99955947; called by muse, mutect2, varscan2
- TRMT112 | c.46del p.V16Wfs*30 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs762738556, COSV50008423; called by mutect2, pindel, varscan2
- TROAP | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV99226714; called by muse, mutect2, varscan2
- TRPC5 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV53283771, COSV53303581; called by muse, mutect2, varscan2
- TRPC6 | c.1312G>T p.G438* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100723505; called by muse, mutect2, varscan2
- TRPM4 | c.2125A>T p.T709S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV99419278; called by muse, varscan2
- TSPYL4 | c.694T>G p.F232V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100126451; called by muse, mutect2
- TST | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.123); catalogued as rs1411699402, COSV99968164; called by muse, mutect2
- TTC30B | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV101282777; called by muse, mutect2, varscan2
- TTLL13P | c.548A>C p.D183A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100296474, COSV60037030; called by muse, mutect2, varscan2
- TTLL4 | c.1603T>G p.S535A | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.621); catalogued as COSV99293144; called by muse, mutect2, varscan2
- TTN | c.69013A>C p.S23005R (on ENST00000591111; = p.S15581R on NM_003319.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | PolyPhen probably damaging (1); catalogued as COSV100600630, COSV60369267; called by muse, mutect2
- TWF1 | c.875T>A p.I292N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV100285978; called by muse, varscan2
- TXNDC16 | c.2198T>C p.I733T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99908975; called by muse, mutect2, varscan2
- TYK2 | c.2848A>G p.I950V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV99314444; called by muse, mutect2, varscan2
- UBQLN1 | c.1432C>A p.P478T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99973236; called by muse, mutect2, varscan2
- UBXN6 | c.507C>A p.D169E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100010965; called by muse, mutect2, varscan2
- UGDH | c.11T>A p.I4N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100328404; called by muse, mutect2, varscan2
- UGT1A5 | c.382T>G p.C128G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529978; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs747493460; called by mutect2, varscan2
- USP20 | c.1454T>C p.L485P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100204127; called by muse, mutect2, varscan2
- USP22 | c.1572C>A p.Y524* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99820134; called by muse, varscan2
- USP29 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99517839; called by muse, varscan2
- USP31 | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.686); catalogued as COSV99564819; called by muse, mutect2, varscan2
- UVSSA | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs188017443, COSV101104352; called by muse, varscan2
- VAV3 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100579338; called by muse, mutect2, varscan2
- VCAN | c.4223T>C p.V1408A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54112540; called by muse, mutect2
- VDAC2 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV100040848; called by muse, mutect2, varscan2
- VMAC | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV100258881; called by muse, mutect2
- VPS13B | c.8663C>A p.P2888H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100661210; called by muse, mutect2, varscan2
- VPS13C | c.4596+2T>C p.X1532_splice (on ENST00000644861 / NM_020821.3; = p.X1489_splice on NM_017684.5) | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99827681; called by muse, mutect2, varscan2
- VPS45 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV100964871; called by muse, mutect2
- VPS9D1 | c.1707T>A p.D569E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101231975; called by muse, mutect2, varscan2
- VRK3 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs775262222, COSV100371440; called by muse, mutect2, varscan2
- VWC2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV100513960; called by muse, mutect2, varscan2
- WDR24 | c.470C>T p.T157I (on ENST00000248142; = p.T95I on NM_032259.4) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99555498; called by muse, mutect2, varscan2
- WDR5 | c.648dup p.V217Rfs*42 | Frame Shift Ins (INS) | VAF 26/66 reads (39%) | catalogued as rs780890680; called by mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR81 | c.4213A>G p.I1405V (on ENST00000409644 / NM_001163809.2; = p.I354V on NM_152348.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV100488682; called by muse, mutect2, varscan2
- WIZ | c.5650G>A p.A1884T (on ENST00000673675 / NM_001371589.1; = p.A789T on NM_021241.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.71); catalogued as COSV99652827; called by muse, mutect2, varscan2
- WNT9A | c.500del p.G167Afs*38 | Frame Shift Del (DEL) | VAF 17/138 reads (12%) | catalogued as rs779992922; called by mutect2, pindel, varscan2
- WRN | c.1404T>G p.D468E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs770053876, COSV99988537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XAF1 | c.544T>C p.F182L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100694990; called by muse, mutect2, varscan2
- ZBTB38 | c.1787A>G p.N596S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1239944227, COSV100375461; called by muse, mutect2, varscan2
- ZBTB7B | c.992A>G p.D331G (on ENST00000292176; = p.D365G on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99420958; called by muse, mutect2, varscan2
- ZC3H12B | c.1098del p.K366Nfs*36 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs1207878861; called by mutect2, pindel, varscan2
- ZCCHC2 | c.3290G>A p.G1097D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs757277626, COSV99502228; called by muse, mutect2, varscan2
- ZFYVE1 | c.1520A>C p.Y507S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100606618; called by muse, mutect2, varscan2
- ZKSCAN4 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101043391; called by muse, mutect2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF184 | c.896T>A p.I299N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99279470; called by muse, mutect2, varscan2
- ZNF253 | c.342A>C p.K114N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100849473, COSV63037045; called by muse, mutect2, varscan2
- ZNF285 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.133); catalogued as COSV100449912; called by muse, mutect2, varscan2
- ZNF300 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.103); catalogued as rs568526962, COSV99199825; called by muse, mutect2, varscan2
- ZNF354A | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1467613771, COSV100234388, COSV59982364; called by muse, mutect2, varscan2
- ZNF365 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV101237948; called by muse, mutect2, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF383 | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61940070; called by muse, mutect2, varscan2
- ZNF407 | c.6247G>A p.V2083I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs781417819, COSV55245734; called by muse, mutect2, varscan2
- ZNF420 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1263939503, COSV100421203; called by muse, mutect2, varscan2
- ZNF512B | c.2369C>T p.P790L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs750224329, COSV99411642; called by muse, mutect2, varscan2
- ZNF582 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV100018559; called by muse, mutect2, varscan2
- ZNF625 | c.984G>T p.E328D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100863453; called by muse, mutect2, varscan2
- ZNF654 | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs983170470, COSV58806023; called by muse, mutect2, varscan2
- ZNF671 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs144208808, COSV100234892; called by muse, mutect2, varscan2
- ZNF672 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.765); catalogued as rs368647505; called by muse, mutect2
- ZNF687 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV99649419; called by muse, mutect2, varscan2
- ZNF768 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.969); catalogued as COSV100776136; called by muse, mutect2, varscan2
- ZNF772 | c.1146A>T p.E382D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV100582778; called by muse, mutect2, varscan2
- ZNF776 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as rs758508423, COSV57816827; called by muse, mutect2, varscan2
- ZNF782 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs147431402; called by muse, mutect2, varscan2
- ZNF862 | c.2804G>T p.R935M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99783315; called by muse, mutect2, varscan2
- ZNF883 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs374489167; called by muse, mutect2, varscan2
- ZNHIT1 | c.465A>C p.*155Cext*70 | Nonstop Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV100521971; called by muse, mutect2, varscan2
- ZSCAN30 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs775943652, COSV99734743; called by muse, mutect2, varscan2
- ZXDC | c.1598T>C p.L533P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100306358; called by mutect2, varscan2
- ABCA9 | c.1570del p.T524Lfs*4 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.5767del p.M1923Cfs*7 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- ANKRD11 | c.7481del p.P2494Lfs*8 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- BARD1 | c.590dup p.A198Gfs*16 | Frame Shift Ins (INS) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- BTNL2 | c.813del p.K272Rfs*9 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- CALB1 | c.601-3del | Splice Region (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- CBLB | c.1848del p.K616Nfs*34 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- CDH10 | c.2187dup p.Y730Lfs*10 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- CDHR2 | c.718dup p.Q240Pfs*13 | Frame Shift Ins (INS) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- CORIN | c.384_385insT p.G129Wfs*70 | Frame Shift Ins (INS) | VAF 20/105 reads (19%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.4710del p.M1571Cfs*32 (on ENST00000651564; = p.M1524Cfs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- CRYZL1 | c.947del p.F316Sfs*45 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- DCAF15 | c.1124dup p.A376Cfs*32 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- DIP2C | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- DPCD | c.69_71del p.R24del | In Frame Del (DEL) | VAF 25/85 reads (29%) | called by mutect2, pindel, varscan2
- EIF3A | c.490_492del p.L164del | In Frame Del (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2
- EIF4G3 | c.2183del p.K728Rfs*35 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- ELF3 | c.764_765del p.K255Rfs*45 | Frame Shift Del (DEL) | VAF 7/73 reads (10%) | called by mutect2, pindel, varscan2
- ELK4 | c.1075del p.S359Hfs*7 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel, varscan2
- ERICH1 | c.487del p.R163Gfs*3 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- EVPL | c.3133del p.E1045Rfs*12 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- FBXL22 | c.487del p.V163* | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- FES | c.1256del p.G419Efs*113 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- FOXRED2 | c.2002del p.L668Wfs*111 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.503dup p.A169Gfs*14 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- GIN1 | c.146del p.K49Sfs*15 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- HIVEP1 | c.2349del p.K784Nfs*13 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- IGHV1-24 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- IL18R1 | c.79del p.H27Tfs*12 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- INPPL1 | c.1322del p.N441Tfs*2 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- ITIH6 | c.3453del p.K1151Nfs*32 | Frame Shift Del (DEL) | VAF 38/154 reads (25%) | called by mutect2, pindel, varscan2
- KCNH4 | c.2943del p.Y982Tfs*24 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel, varscan2
- KDM5B | c.3355del p.S1119Afs*4 | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.11101del p.T3701Lfs*118 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- KIF11 | c.2018del p.K673Rfs*3 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- KIF26B | c.2660dup p.D888Rfs*89 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by pindel, varscan2
- KMT2A | c.4914del p.E1639Sfs*6 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- KMT2B | c.6641del p.P2214Qfs*2 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- MACF1 | c.2560del p.T854Pfs*5 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- MEP1B | c.147del p.F49Lfs*31 | Frame Shift Del (DEL) | VAF 11/78 reads (14%) | called by pindel, varscan2
- METTL6 | c.666del p.F222Lfs*19 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- MIDEAS | c.3073del p.T1025Qfs*68 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- MRPL2 | c.839del p.G280Afs*13 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | called by mutect2, pindel, varscan2
- MUC2 | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NAV1 | c.1834_1836del p.P612del | In Frame Del (DEL) | VAF 7/75 reads (9%) | called by pindel, varscan2
- NEK11 | c.970del p.R324Gfs*7 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- NEK7 | c.192del p.V65Cfs*6 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- NLGN4X | c.246del p.T83Lfs*53 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- NMNAT2 | c.403del p.Q135Sfs*42 | Frame Shift Del (DEL) | VAF 21/133 reads (16%) | called by mutect2, pindel, varscan2
- OR13C2 | c.835del p.I279Lfs*8 | Frame Shift Del (DEL) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- OR1F1 | c.30dup p.E11Rfs*111 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- OSGEPL1 | c.419del p.K140Sfs*18 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- OSGEPL1 | c.205del p.T69Lfs*5 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | called by mutect2, pindel
- PDGFRA | c.2410dup p.R804Pfs*15 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- PEX1 | c.429del p.P144Lfs*17 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- PHRF1 | c.647del p.P216Lfs*29 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- PKHD1 | c.4660del p.Y1554Ifs*38 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- PLCZ1 | c.132del p.F44Lfs*7 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- PXN | c.983del p.P328Rfs*18 (on ENST00000228307 / NM_001080855.3; = p.P294Rfs*18 on NM_002859.4) | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- RAI1 | c.2396del p.P799Lfs*20 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- SARS1 | c.1337_1340del p.T446Rfs*10 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by pindel, varscan2
- SCLT1 | c.1268_1269del p.K423Sfs*12 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- SEC14L4 | c.1211dup p.T405Nfs*49 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, pindel, varscan2
- SETMAR | c.447del p.G150Afs*24 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- SHISA5 | c.707del p.P236Rfs*23 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- SNAP23 | c.146del p.K49Rfs*4 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
222 further variants in this file (19 protein-altering or splice-affecting, 183 silent, 20 other) are not listed here.
